Somatic mutation profile of tumor specimen TARGET-40-NAAGKL-01A (aliquot TARGET-40-NAAGKL-01A-01D) from TARGET case TARGET-40-NAAGKL, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.5 years (6,012 days).
Specimen TARGET-40-NAAGKL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7af98994-b77f-4e6e-853b-dfa25621024a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGKL-10B (Blood Derived Normal), aliquot TARGET-40-NAAGKL-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f523416-5f21-4c16-a177-6c75360630bb

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.5986G>A p.G1996R | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs377010256; called by muse, mutect2, varscan2
- KAT6A | c.2806C>A p.P936T | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs367785766; called by muse, mutect2, varscan2
- UNC13C | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs746269797, COSV52862396; called by muse, mutect2, varscan2
- UNC5C | c.2671G>T p.V891L | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV71657932, COSV71658965; called by muse, mutect2, varscan2
- ADGRV1 | c.7243A>C p.I2415L | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- DAGLA | c.2021_2027del p.L674Qfs*6 | Frame Shift Del (DEL) | VAF 7/13 reads (54%) | called by mutect2, varscan2
- FAM13A | c.796A>G p.T266A | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HUWE1 | c.6929A>G p.Q2310R | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCLO | c.10040G>C p.S3347T | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.11445A>C p.E3815D | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- UBE3A | c.1102A>G p.I368V | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DNAH9 | c.5976T>G p.P1992= | Silent (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2
- MUC16 | c.37941C>A p.G12647= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs75995954, COSV67470890, COSV67493606; called by muse, mutect2, varscan2
- OTOF | c.4581C>T p.R1527= (on ENST00000272371 / NM_194248.3; = p.R760= on NM_004802.4) | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs560125081; called by muse, mutect2, varscan2
